Gene-level copy-number profile of tumor specimen TCGA-E1-A7YM-01A from TCGA case TCGA-E1-A7YM, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 63.7 years (23,263 days).
Specimen TCGA-E1-A7YM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.b0957649-e958-498b-ac47-9aa2ca6a99b4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-E1-A7YM-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c8fbdeea-647d-4b73-836a-d32a402f171b

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 42; copy number 1: 8; copy number 2: 9,076; copy number 3: 1,803; copy number 4: 45,877; copy number 6: 3,014.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-E1-A7YM-01A-11D-A349-01): tumor purity 0.5, ploidy 1.95, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 42 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:7,915,871–9,198,906, 42 genes: TNFRSF9, AL009183.1, PARK7, Y_RNA, AL034417.4, AL034417.3, ERRFI1, AL034417.2, AL034417.1, AL358876.1, LINC01714, RNU1-7P, AL358876.2, RNU6-991P, SLC45A1, Y_RNA, RERE, RERE-AS1, AL096855.1, AL096855.2, RPL7P11, RPL7P7, Y_RNA, AL357552.1, AL357552.2, RPL23AP19, ENO1, MIR6728, ENO1-AS1, RNU6-304P, HMGN2P17, AL139415.1, AL139415.2, CA6, RN7SL451P, SLC2A7, SLC2A5, AL158048.1, GPR157, MIR34AHG, MIR34A, LNCTAM34A.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
